Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A44M, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A44M-01A (Primary Tumor).

Procurement Date: Laterality: Tumor consists of trabeculae or folliculae or papillae having a broad fibrovascular stalk covered by a single to multiple layers of cuboidal epithelial cells. Tumor invades in capsule or vessel or benign tissue. The cells tend to maintain their polarity. Nuclei are quite regular and contain finely dispersed chromatin, or intranuclear grooves. Tumor is predominant invasion of inflammatory cells

Path Report: Thyroid Gland Tumor Checklist

Tumor type: Papillary carcinoma

Tumor size: 1 x 1 x 0.5 cm

Laterality: Right

Focality: Unifocal

Extrathyroidal extension: No

Markers and special stains: None

Additional comments: Tumor invades in capsule or vessel or benign tissue.

ICD-O-3

Carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS
8-31-12 C73.9
RD

Kmt

8/14/12

kw
8/14/12

Source: NCI Genomic Data Commons file d94f62ff-f051-44e5-a414-322aa2cec1ee (TCGA-E8-A44M.596CF3BD-A887-4BDB-BFCA-10046877BC94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).